Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A4XF, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A4XF-01A (Primary Tumor).

[page 1 of 2]
Process
Received
Report

Final Diagnosis:

A-C. Brain, right frontal mass #1 and #2 and right deep frontal mass, resections: WHO grade III (of IV) fibrillary astrocytoma (anaplastic astrocytoma).

Seen in consultation with

Preliminary Frozen Section Consultation:

A. Brain, right frontal mass #1, smears: High-grade glial neoplasm, at least anaplastic astrocytoma.

Seen in consultation with

Intraoperative cytologic smear(s) interpretation performed by.

Gross Description:

continued next page Page 1 of 2

1CD-0-3
astrocytoma, anaplastic 9401/3
Site: brain, frontal lobe C71-1

fu
10/23/12

[page 2 of 2]
A. Received fresh labeled "right frontal brain mass" is a 5.5 x 5.2 x 2.2 cm portion of brain. Smears prepared. Representative sections are submitted. Grossed by

B. Received fresh labeled "right deep frontal brain mass" is a 2.8 x 1.9 x 0.7 cm portion of friable brain. All submitted for permanent sections only. Grossed by

C. Received fresh labeled "right frontal brain mass" is an 8.1 x 4.2 x 0.9 cm aggregate of pink-tan soft tissue. Representative sections are submitted for permanent sections only. Grossed by

Block Summary:

Part A: Right frontal brain mass

- 1 Cortical surface 1
- 2 Cortical surface 2
- 3 White matter mg 1
- 4 White matter mg 2
- 5 Rt frontal brain tx 1
- 6 Rt frontal brain tx 2

Part B: Right deep frontal brain mass

- 1 Rt deep frontal brain mass 1
- 2 Rt deep frontal brain mass 2
- 3 Rt deep frontal brain mass 3
- 4 Rt deep frontal brain mass 4

Part C: Right frontal brain mass

- 1 Rt frontal brain mass 1
- 2 Rt frontal brain mass 2
- 3 Rt frontal brain mass 3
- 4 Rt frontal brain mass 4

END OF REPORT

Page 2 of 2

	Yes	No
Discrepancy		✓
Any		✓
Primary Notes		✓

1.2/12

Source: NCI Genomic Data Commons file 722be0fd-8ec2-4f79-9825-6996364943fc (TCGA-DB-A4XF.E9D4CC67-D5FC-4E81-91EB-869D93114475.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).